TARGET case TARGET-40-NAAGZZ — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/919adeef-368a-536b-b059-ad3af22504f1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 17 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 17.6 years (6,434 days); Year of diagnosis: 2010; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,855 days (5.1 years).
   Pathology details: Necrosis percent: 41.
   Treatment given: Protocol identifier: GLATO 2006.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Methotrexate.

Follow-up (1 entry)
- Days to follow up: 1,855 days (5.1 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,855; Year of follow up: 2015.

Biospecimens (1 sample)
- Sample TARGET-40-NAAGZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAGZZ-01A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 98
- % Non Tumor Nuclei: Top from Biopsy: 2
- % Cellular Tumor: Top from Biopsy: 90
- % Normal: Top from Biopsy: 0
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 10
- % Tumor Nuclei: Bottom from Biopsy: 98
- % Non Tumor Nuclei: Bottom from Biopsy: 2
- % Cellular Tumor: Bottom from Biopsy: 95
- % Normal: Bottom from Biopsy: 0
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 5
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAGZZ-08A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 0
- % Non Tumor Nuclei: Top from Biopsy: 100
- % Cellular Tumor: Top from Biopsy: 0
- % Normal: Top from Biopsy: 15
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 85
- % Tumor Nuclei: Bottom from Biopsy: 0
- % Non Tumor Nuclei: Bottom from Biopsy: 100
- % Cellular Tumor: Bottom from Biopsy: 0
- % Normal: Bottom from Biopsy: 5
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 95
- PASS/FAIL: fail (0%T)

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1855
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Time to first SMN in days: 0
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Therapy: CIS+DOX+MTX
